Gene-level copy-number profile of tumor specimen C3N-01802-01 from CPTAC case C3N-01802, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 85.0 years (31,052 days).
Specimen C3N-01802-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebb1f665-2a2a-4f14-affb-ff61cba5a826.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01802-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/b73fa5f4-684f-47d9-a264-b15fbb40f6ad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,291; copy number 2: 41,620; copy number 3: 6,475; copy number 4: 1,407; copy number 5: 454; copy number 6: 103; copy number 7: 30; copy number 8: 1; copy number 9: 3; copy number 10: 3; copy number 11: 3; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 598 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:27,625,638–27,988,087, 8 genes, copy number 6 (within-gene range 3–6): CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS.
- chr2:27,896,116–27,897,195, 1 gene, copy number 6 (within-gene range 4–6): MYG1P1.
- chr2:28,384,409–28,644,142, 7 genes, copy number 6–9 (within-gene range 2–9): FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7.
- chr2:69,829,660–70,248,660, 14 genes, copy number 5: GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816, C2orf42, TIA1.
- chr2:70,607,618–71,064,743, 22 genes, copy number 5 (within-gene range 3–5): ADD2, AC005234.2, AC005234.1, FIGLA, HMGN2P21, CLEC4F, MOB4P1, CD207, LINC01143, AC007040.3, VAX2, ATP6V1B1, AC007040.2, ATP6V1B1-AS1, ELOCP21, RN7SL160P, ANKRD53, TEX261, AC007040.1, AC007881.2, OR7E91P, OR7E46P.
- chr2:112,589,040–113,563,298, 34 genes, copy number 5 (within-gene range 4–5): AC012442.2, AC012442.1, AC079922.1, AC079922.2, SLC20A1, NT5DC4, CKAP2L, IL1A, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4.
- chr3:52,048,919–53,347,586, 60 genes, copy number 5–6: DUSP7, POC1A, ALDOAP1, ALAS1, AC097637.2, TLR9, AC097637.1, TWF2, AC006252.1, PPM1M, WDR82, MIRLET7G, GLYCTK, GLYCTK-AS1, MIR135A1, DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2, SMIM4, PBRM1, RNU6-856P, RNU6ATAC16P, GNL3, AC104446.3, AC104446.1, SNORD19, SNORD19B, SNORD19C, SNORD69, GLT8D1, SPCS1, NEK4, AC104446.2, AC006254.2, AC006254.3, ITIH1, ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1, STIMATE-MUSTN1, STIMATE, MIR8064, AC099667.1, SFMBT1, AC096887.1, AC096887.2, SERBP1P3, RFT1, PRKCD, TKT, DCP1A, Y_RNA.
- chr3:53,333,060–53,333,128, 1 gene, copy number 6: SNORD38C.
- chr3:56,557,161–56,683,237, 2 genes, copy number 5: CCDC66, TASOR.
- chr3:168,858,659–169,663,775, 8 genes, copy number 6–26 (within-gene range 4–26): RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1.
- chr3:172,425,850–173,336,965, 17 genes, copy number 5–7: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:190,428,655–190,659,750, 5 genes, copy number 5: TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1.
- chr5:139,341,587–139,844,466, 25 genes, copy number 5: PAIP2, AC135457.1, SLC23A1, MZB1, PROB1, SPATA24, DNAJC18, AC142391.1, RNU5B-4P, ECSCR, STING1, AC138517.1, NCOA4P4, UBE2D2, Y_RNA, H3P25, AC113361.1, CXXC5, CXXC5-AS1, AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4, PSD2.
- chr5:149,694,237–150,222,788, 19 genes, copy number 5 (within-gene range 3–5): AC022100.1, U3, RN7SL868P, PPARGC1B, MIR378A, PDE6A, MFFP2, Y_RNA, SLC26A2, TIGD6, HMGXB3, AC011406.1, RPS20P4, CSF1R, RPL7P1, Y_RNA, PDGFRB, CDX1, SLC6A7.
- chr6:106,695,535–107,115,515, 7 genes, copy number 7: LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3.
- chr6:136,231,024–137,219,449, 25 genes, copy number 5: MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1.
- chr8:99,960,936–101,208,558, 40 genes, copy number 5: RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4.
- chr8:127,072,694–127,227,541, 1 gene, copy number 11 (within-gene range 2–11): CASC19.
- chr9:68,232,003–68,300,035, 2 genes, copy number 11: CBWD3, AL353608.4.
- chr11:34,621,093–35,232,402, 10 genes, copy number 5: EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1.
- chr11:67,266,473–67,906,350, 49 genes, copy number 5: GRK2, ANKRD13D, SSH3, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134, AIP, MIR6752, PITPNM1, CDK2AP2, CABP2, GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4, ALG1L8P, FAM86C2P, ENPP7P7, AP003716.1, LINC02754, RNU6-46P.
- chr12:56,029,649–56,636,816, 45 genes, copy number 5 (within-gene range 4–5): AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P, BAZ2A.
- chr14:73,237,497–73,274,640, 4 genes, copy number 7: PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr14:76,886,377–77,086,457, 13 genes, copy number 6: RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5.
- chr14:105,093,609–105,450,106, 15 genes, copy number 5 (within-gene range 4–5): LINC02298, AL512356.4, AL512356.3, AL512356.2, JAG2, MIR6765, AL512356.1, NUDT14, BRF1, BTBD6, PACS2, AL928654.4, RPS20P33, TEX22, AL928654.1.
- chr15:71,822,291–72,118,577, 3 genes, copy number 6 (within-gene range 3–6): MYO9A, RNA5SP399, AC022872.1.
- chr17:28,444,063–30,108,452, 96 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:37,084,992–37,802,788, 18 genes, copy number 5: ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1.
- chr17:44,957,992–45,109,016, 1 gene, copy number 6 (within-gene range 3–6): NMT1.
- chr17:45,071,442–45,171,584, 9 genes, copy number 6: Y_RNA, PLCD3, MIR6784, ACBD4, AC142472.1, HEXIM1, AC138150.1, HEXIM2, AC138150.2.
- chr19:44,725,984–44,760,044, 3 genes, copy number 10: AC243964.2, BCL3, MIR8085.
- chr20:33,655,701–33,854,366, 13 genes, copy number 5: AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B.
- chr20:50,040,716–50,192,668, 9 genes, copy number 5: TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB.
- chr20:62,302,093–62,447,677, 11 genes, copy number 5: ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1.
- chr22:18,715,815–18,719,341, 1 gene, copy number 8: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 8,291. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
